Somatic mutation profile of tumor specimen TCGA-TM-A7C3-01A (aliquot TCGA-TM-A7C3-01A-11D-A32B-08) from TCGA case TCGA-TM-A7C3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 43.9 years (16,021 days).
Specimen TCGA-TM-A7C3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cdfd526-e993-4cbf-b6d3-b56c0fe8b80b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A7C3-10A (Blood Derived Normal), aliquot TCGA-TM-A7C3-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d69fd92-bf48-40c4-a6a1-f485e0fcb762

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 15, Nonsense Mutation 5, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 959/1355 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FANCA | c.3482C>T p.T1161M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs142833057; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.1576G>C p.D526H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV100580225; called by muse, mutect2, varscan2
- ACAA2 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV99551996; called by muse, mutect2, varscan2
- ANO1 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV60285547; called by muse, varscan2
- ARHGEF2 | c.359C>T p.P120L (on ENST00000361247 / NM_001162383.2; = p.P93L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100561069; called by muse, mutect2, varscan2
- ATP1A3 | c.862G>A p.A288T (on ENST00000545399 / NM_001256214.2; = p.A275T on NM_152296.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs868987618, COSV57485725; called by muse, mutect2, varscan2
- CADPS | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760662640, COSV99340375; called by muse, mutect2, varscan2
- COL6A3 | c.4108G>A p.A1370T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as rs372234605, COSV55085755; ClinVar: uncertain significance; called by mutect2, varscan2
- CPSF3 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs1478420401, COSV99433170; called by muse, mutect2, varscan2
- DGKG | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1052527740, COSV99404190; called by muse, mutect2, varscan2
- DOCK5 | c.4675G>A p.V1559I | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs756518291, COSV52396868; called by muse, mutect2, varscan2
- EFNA3 | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs143760648; called by muse, mutect2, varscan2
- FASTKD1 | c.655_657del p.L219del | In Frame Del (DEL) | VAF 5/23 reads (22%) | catalogued as rs757208851; called by pindel, varscan2
- GAS2L2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587627832; called by muse, mutect2, varscan2
- GPR37 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767810765, COSV58259947; called by muse, mutect2, varscan2
- GRIN2B | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs776323617, COSV74208162; called by muse, mutect2, varscan2
- GRM8 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs780568800, COSV58821868; called by muse, mutect2, varscan2
- IRF9 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 21/117 reads (18%) | catalogued as COSV100138256; called by muse, mutect2, varscan2
- ITPRID1 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.295); catalogued as COSV100087314; called by muse, mutect2, varscan2
- KCNB2 | c.40T>C p.S14P | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV101578953; called by muse, mutect2, varscan2
- KRT13 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs746117318, COSV55839059; called by muse, mutect2, varscan2
- MAGEA10 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.07); catalogued as rs145553450, COSV54884254; called by muse, mutect2, varscan2
- MAP7D2 | c.1604A>C p.Q535P | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101107517; called by muse, mutect2, varscan2
- MED12 | c.4541G>A p.W1514* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100379542; called by muse, mutect2, varscan2
- MKI67 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs764041173, COSV100896911, COSV64073095; called by muse, mutect2, varscan2
- MKNK1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as rs147526106; called by muse, mutect2, varscan2
- MTUS2 | c.357T>A p.D119E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101462343; called by muse, mutect2, varscan2
- MUC5B | c.13580C>A p.S4527Y | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as COSV101500668; called by muse, mutect2, varscan2
- NIPBL | c.3487C>T p.P1163S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761353689, COSV56969454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPC1L1 | c.3097A>G p.S1033G | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99213344; called by muse, mutect2, varscan2
- NPTX1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs1447587351, COSV60774615; called by muse, mutect2, varscan2
- OR51T1 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100434460; called by muse, mutect2, varscan2
- PBX4 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 63/476 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV99232415; called by muse, mutect2, varscan2
- PCDHGA5 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as COSV54029541; called by muse, mutect2, varscan2
- PLXNB3 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs373965130, COSV62803375; called by muse, mutect2, varscan2
- PRMT9 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as rs749802393, COSV100482336; called by muse, mutect2, varscan2
- RANBP17 | c.2821G>A p.V941I | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.481); catalogued as rs141341938; called by muse, mutect2, varscan2
- RAVER2 | c.1621C>G p.L541V (on ENST00000294428 / NM_001366165.1; = p.L528V on NM_018211.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99605562; called by muse, mutect2
- RIMS1 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV53452838; called by muse, mutect2, varscan2
- SCN3A | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV99328189; called by muse, mutect2, varscan2
- SEMG1 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.981); catalogued as rs199781597; called by muse, mutect2, varscan2
- SIGLEC1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs749127081, COSV99170224; called by muse, mutect2, varscan2
- SLC13A2 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs782087379, COSV58996941; called by muse, mutect2, varscan2
- SOAT1 | c.1325A>G p.K442R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs951136603, COSV100859033; called by muse, mutect2, varscan2
- STAG2 | c.3473G>A p.R1158H | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1430304708, COSV99495010; called by muse, mutect2, varscan2
- TENM3 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1185466419, COSV69315982; called by muse, mutect2, varscan2
- THOP1 | c.1400A>G p.E467G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100310752; called by muse, mutect2, varscan2
- TRAV13-1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as rs769916683; called by muse, mutect2, varscan2
- USH2A | c.15092G>A p.R5031Q | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs755653202, COSV100240873, COSV56339321; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1424C>A p.S475* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100362995; called by muse, mutect2, varscan2
- PRAMEF18 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AHNAK2 | c.3033G>A p.S1011= | Silent (SNP) | VAF 137/294 reads (47%) | catalogued as rs368288854; called by muse, mutect2, varscan2
- ATP11C | c.1914T>C p.D638= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV100558446; called by muse, mutect2, varscan2
- CNTROB | c.2076C>T p.D692= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as rs563111997, COSV100972749; called by muse, mutect2, varscan2
- COL2A1 | c.1905T>C p.D635= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100477281; called by muse, mutect2, varscan2
- EEF1A1 | c.1347C>G p.G449= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100303405; called by muse, mutect2, varscan2
- MNS1 | c.1443C>T p.F481= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV53070287; called by muse, mutect2, varscan2
- MS4A6A | c.126C>T p.H42= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs113133013, COSV60617004; called by muse, mutect2, varscan2
- OR2T4 | c.813C>A p.A271= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as rs183344109, COSV100822584, COSV63544574; called by muse, mutect2, varscan2
- PCDHGA2 | c.756G>A p.P252= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs765859037, COSV99545136; called by muse, mutect2, varscan2
- S1PR4 | c.342G>A p.A114= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs369355383; called by muse, mutect2
- SLC9A3 | c.663C>T p.D221= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs1024234444, COSV99376562; called by muse, mutect2, varscan2
- SMARCA4 | c.4740G>A p.E1580= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100759038; called by muse, mutect2, varscan2
- STAG2 | c.570C>T p.I190= | Silent (SNP) | VAF 79/177 reads (45%) | catalogued as COSV99495005; called by muse, mutect2, varscan2
- TAS2R31 | c.18C>T p.P6= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV101115437; called by muse, mutect2, varscan2
- TTLL4 | c.561G>A p.A187= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs528979213, COSV99293690; called by muse, mutect2, varscan2
- WNK1 | c.2140-2325G>A | Intron (SNP) | VAF 48/225 reads (21%) | catalogued as COSV100268324; called by muse, mutect2, varscan2
